Surgical pathology report (de-identified scan), TCGA case TCGA-5A-A8ZG, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Wake Forest University, specimen TCGA-5A-A8ZG-01A (Primary Tumor).

[page 1 of 5]
ACCESSION NUMBER:
RECEIVED:
ORDERING PHYSICIAN:
PATIENT NAME:
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS
MICROSCOPIC EXAMINATION AND DIAGNOSIS

A. HILAR LYMPH NODE, EXCISION:
Metastatic adenocarcinoma (2 of 3 lymph nodes).
Numerous non-necrotizing granulomas (see comment).

B. HILAR LYMPH NODE #2, EXCISION:
Adipose tissue.
No lymph nodes identified.
No malignancy identified.

C. LEFT LOBE OF LIVER, PARTIAL HEPATECTOMY:
Adenocarcinoma, three foci (5.8 x 5.3 x 3.5 cm, 0.3 cm,
microscopic focus).
-See oncology protocol and comment.
Mild steatohepatitis with pericellular and periportal
fibrosis (Brunt stage 2 of 4).
Scattered non-necrotizing granulomas.

INTRAHEPATIC BILE DUCTS RESECTION-CANCER PROTOCOL

SPECIMEN: Liver
PROCEDURE: Partial hepatectomy
TUMOR SIZE: Largest focus= 5.8 x 5.3 x 3.5 cm
TUMOR FOCALITY: Multiple
HISTOLOGIC TYPE: Adenocarcinoma consistent with
choolangiocarcinoma (see comment)
HISTOLOGIC GRADE: Grade 2
TUMOR GROWTH PATTERN: Mass-forming
MICROSCOPIC TUMOR EXTENSION: Tumor confined to hepatic parenchyma
(see comment)
MARGINS:
HEPATIC PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1.7 cm
BILE DUCT MARGIN: Cannot be assessed
LYMPH-VASCULAR INVASION: Small vessel invasion present
PERINEURAL INVASION: Not identified

ICD-O-3
Cholangiocarcinoma 8160/3
Site ^{cof} Intrahepatic bile duct
^{path} Liver C22.0
C22.1
Jan 1/21/14

[page 2 of 5]
PATHOLOGIC STAGING (pTNM)

TNM DESCRIPTORS: m (multiple primary tumors)

PRIMARY TUMOR (pT): pT2b

REGIONAL LYMPH NODES (pN): pN1

Number examined: 3

Number involved: 2

DISTANT METASTASIS (pM): Not applicable

COMMENT:

Immunohistochemistry was obtained on the largest focus of adenocarcinoma in the liver. The neoplasm is immunoreactive for cytokeratin 7, CEA and CA19-9 (interpretation hampered by high background staining) and is negative for cytokeratin 20, CDX2 and TTF-1. While not specific, the immunoprofile is compatible with a diagnosis of cholangiocarcinoma. However, it should be noted that other primary sites, including pancreas, are not excluded by the immunohistochemical stain results.

A membranous piece of tissue was adherent to the liver in the region of the tumor. However, microscopically no definite extension of the neoplasm beyond the liver capsule is observed.

The presence of metastatic carcinoma in the hilar lymph nodes was confirmed by an immunohistochemical stain for cytokeratin AE1/AE3. Special stains for acid-fast bacilli and fungi have been obtained and will be reported in an addendum.

Trichrome and reticulin special stains were utilized to assess the presence of fibrosis in the non-neoplastic hepatic parenchyma. A Prussian blue iron stain is essentially negative.

_____ has reviewed the section of non-neoplastic liver and the special stains. He concurs with the interpretation of mild steatohepatitis, Brunt stage 2.

The histochemical and immunohistochemical positive controls stained appropriately.

"These tests were developed and their performance characteristics determined by _____

_____. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as

[page 3 of 5]
investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing."

I have personally reviewed the slides and/or other related materials referenced, and have edited the report as part of my pathologic assessment and final interpretation.

Electronically Signed Out By:

Specimen(s) Received

A: Hilar lymph node
B: Hilar lymph node #2
C: Left lobe of liver

Clinical History

Malignant neoplasm of liver

Gross Description

A. Received labeled "hilar lymph node "is a 4.3 x 2.8 x 1.2 cm yellow-tan piece of adipose tissue. The specimen is dissected to reveal three lymph node candidates ranging from 3.5 x 2 x 1.1 cm to 0.5 x 0.2 x 0.2cm. The specimen is entirely submitted for histopathologic examination as follows:

BLOCK SUMMARY:

A1 one lymph node candidate bisected and entirely submitted

A2-7 one lymph node candidate serially sectioned and entirely submitted

A8 one lymph node candidate entirely submitted

A9 remaining fat entirely submitted

B. Received labeled "hilar lymph node #2 "is a 1.1 x 1 x 0.7 cm yellow-tan piece of adipose tissue. The specimen is dissected to reveal two lymph node candidates which are 0.6 x 0.5 x 0.2 cm and 0.8 x 0.5 x 0.2 cm. The specimen is entirely submitted as

[page 4 of 5]
follows:

BLOCK SUMMARY:

B1 2 lymph node candidates entirely submitted

B2 remaining adipose tissue entirely submitted

C. Received labeled "left lobe of liver" it is a 584 g piece of liver (151 g of the normal tissue was removed for research). The specimen is 15 x 10.3 x 5.5 cm with a 6 x 2 x 0.8 cm ligament attached. The resection margin is 14.8 x 7 cm and is inked black. The liver capsule is smooth and intact with a 7.1 x 1.8 cm attached piece of membranous tissue. On the surface of the capsule to include the attached membranous tissue, there is a 3.5 x 3.7 cm of area of puckering. This region is inked black for identification. The specimen is serially sectioned to reveal a dense, tan-yellow mass, 5.8 x 3.5 x 5.3 cm. The mass abuts the liver capsule, and is suspicious for invading the overlying membranous tissue. The mass is 1.7 cm away from the closest resection margin (this measurement was relayed to the surgeons as a gross margin). A 0.3 x 0.3 cm satellite nodule is 4.9 cm away from the closest resection margin and 1.8 cm away from the mass. At the resection margin, there is a 0.2 cm zone of pallor, probably due to cautery. Representative sections are submitted as follows:

BLOCK SUMMARY:

C1 radial section of closest resection margin to include tumor

C2 two representative section of tumor in relation to capsule and attached membranous tissue

C3 representative section of tumor in relation to vasculature

C4 2 representative sections of tumor in relation to normal parenchyma

C5 representative section of tumor

C6 representative section of an uninvolved capsule and parenchyma

C7 satellite nodule to include capsule, submitted entirely

C8 representative section of ligament of Treitz

C9 representative section of resection margin pallor

[page 5 of 5]
PROCEDURES/ADDENDA

ADDENDUM Date Ordered: Date
Reported:

Addendum Comment

Special stains for acid-fast bacilli and fungi
(GMS) were obtained on block A2 and are interpreted as negative.
Of note, the GMS-stained section exhibits a single pale-staining
budding yeast-like structure that is slightly out of the plane of
section. This structure is thought to most likely represent an
artifact.

The histochemical positive control stained appropriately.

I have personally reviewed the slides and/or other related
materials referenced, and have edited the report as part of my
pathologic assessment and final interpretation.

Electronically Signed Out By:

Criteria:	/w 12/15/13		Yes	No

Source: NCI Genomic Data Commons file 85d1a467-636d-4013-af46-504024f62d3f (TCGA-5A-A8ZG.DFA3212C-41A5-4199-A6FB-A3A90C524DA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).